CCDI case PBCGLD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d260223f-8b34-444a-ac92-294ea642e9e6

Demographics
Sex at birth: female.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.8 years (4,301 days).

Biospecimens (3 samples)
- Sample 0DRHPZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRHQ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRHQ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
